Somatic mutation profile of tumor specimen SM-JU34D (aliquot 7316UP-160) from CPTAC case C231855, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU34D: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45e7d9fe-c4f2-4ca5-a6b2-e537da3e057c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105288 (Blood Derived Normal), aliquot 7316UP-421-1105288; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1319d855-de6b-49b7-a1a3-7afe30242dd9

The open-access MAF lists 65 somatic variants for this specimen: 43 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 19, Frame Shift Del 3, Splice Site 2, Intron 1, In Frame Del 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 31/68 reads (46%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2
- AHNAK2 | c.10157G>A p.G3386D | Missense Mutation (SNP) | VAF 126/257 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs199830560; called by muse, mutect2, varscan2
- ALOX15B | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749072236; called by muse, mutect2, varscan2
- ARGFX | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770818565, COSV100544207; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1157G>A p.R386Q (on ENST00000272238 / NM_001039362.2; = p.R340Q on NM_144583.4) | Missense Mutation (SNP) | VAF 40/146 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as rs1179657289, COSV55353294; called by muse, mutect2, varscan2
- B2M | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 151/459 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs368160918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E4F1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs540780876; called by muse, mutect2, varscan2
- HOXD13 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs927690691, CM127648; called by muse, mutect2, varscan2
- LRRFIP1 | c.42_45del p.C14* | Frame Shift Del (DEL) | VAF 23/118 reads (19%) | catalogued as rs769674928; called by mutect2, pindel, varscan2
- MX2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.89); PolyPhen benign (0.227); catalogued as rs745448850, COSV58096513; called by muse, mutect2, varscan2
- MYCN | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 39/165 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV55257623; called by muse, mutect2, varscan2
- OR5M1 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 70/167 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs768719281, COSV101591625; called by muse, mutect2, varscan2
- PKP2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 106/284 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs148480056, CM132691, COSV50730692; called by muse, mutect2, varscan2
- RFX6 | c.504G>A p.K168= | Splice Region (SNP) | VAF 94/278 reads (34%) | catalogued as COSV60583869; called by muse, mutect2, varscan2
- SLC17A9 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 83/277 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as rs201493327, COSV64847130; called by muse, mutect2, varscan2
- SLC9C1 | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1161427551; called by muse, mutect2
- SPATA16 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 98/319 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63532145, COSV63532636; called by muse, mutect2, varscan2
- TERT | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 93/254 reads (37%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.689); catalogued as rs768398955, COSV57205187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMEM184A | c.1156G>A p.G386S | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs112333641; called by muse, mutect2, varscan2
- TRAK1 | c.606_608del p.S203del (on ENST00000327628 / NM_001349247.2; = p.S145del on NM_014965.5) | In Frame Del (DEL) | VAF 40/122 reads (33%) | catalogued as rs1559899029; called by pindel, varscan2
- ZDHHC1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs145809493; called by muse, mutect2, varscan2
- AKAP7 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- APOBEC1 | c.16+2T>G p.X6_splice | Splice Site (SNP) | VAF 63/177 reads (36%) | called by muse, mutect2, varscan2
- ATP5MC3 | c.124T>G p.S42A | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- BTBD7 | c.2322C>A p.N774K | Missense Mutation (SNP) | VAF 46/71 reads (65%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDK3 | c.517A>C p.I173L | Missense Mutation (SNP) | VAF 134/312 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CHD6 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 64/230 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CNOT3 | c.548T>C p.L183P | Missense Mutation (SNP) | VAF 21/290 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCT | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 89/163 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLL3 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM131B | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- GAL3ST3 | c.440A>C p.Y147S | Missense Mutation (SNP) | VAF 88/278 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KCNG1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 97/298 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- KCNK1 | c.263A>G p.Y88C | Missense Mutation (SNP) | VAF 16/240 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MARCHF6 | c.2657A>C p.Q886P | Missense Mutation (SNP) | VAF 62/173 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MYLK3 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 141/407 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PHRF1 | c.3161C>T p.S1054F (on ENST00000264555 / NM_001286581.2; = p.S1053F on NM_020901.4) | Missense Mutation (SNP) | VAF 119/332 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTEN | c.580_590del p.L194Dfs*4 | Frame Shift Del (DEL) | VAF 69/122 reads (57%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SPAG5 | c.1478T>C p.M493T | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TMEM63A | c.1108_1117del p.C370Rfs*64 | Frame Shift Del (DEL) | VAF 25/89 reads (28%) | called by mutect2, pindel, varscan2
- UNC5D | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 60/167 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ZNF827 | c.3173C>A p.T1058N | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ACSM4 | c.564A>G p.K188= | Silent (SNP) | VAF 117/335 reads (35%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.1285C>T p.L429= | Silent (SNP) | VAF 36/106 reads (34%) | called by muse, mutect2, varscan2
- BARHL1 | c.945C>G p.P315= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as rs550911455; called by muse, mutect2
- BCL11A | c.1575C>T p.S525= (on ENST00000335712 / NM_001365609.1; = p.S559= on NM_018014.4) | Silent (SNP) | VAF 70/240 reads (29%) | catalogued as COSV59624728; called by muse, mutect2, varscan2
- DCAF6 | c.45G>A p.R15= | Silent (SNP) | VAF 126/363 reads (35%) | catalogued as rs1228017790; called by muse, mutect2, varscan2
- DDC | c.510G>A p.A170= | Silent (SNP) | VAF 189/541 reads (35%) | catalogued as rs774547345, COSV63563798; called by muse, mutect2, varscan2
- DNAH2 | c.6765C>T p.R2255= | Silent (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- FAM83B | c.3003A>G p.Q1001= | Silent (SNP) | VAF 22/69 reads (32%) | called by mutect2, varscan2
- HMCN1 | c.3564G>A p.V1188= | Silent (SNP) | VAF 79/215 reads (37%) | catalogued as COSV54910297; called by muse, mutect2, varscan2
- KRT13 | c.1239C>T p.D413= | Silent (SNP) | VAF 130/401 reads (32%) | catalogued as rs552137773, COSV55840148; called by muse, mutect2, varscan2
- LHX8 | c.747C>T p.N249= | Silent (SNP) | VAF 113/345 reads (33%) | catalogued as rs1209668255; called by muse, mutect2, varscan2
- PLCE1 | c.174C>T p.N58= | Silent (SNP) | VAF 166/293 reads (57%) | catalogued as rs761575973; called by muse, mutect2, varscan2
- POTEC | c.402C>T p.H134= | Silent (SNP) | VAF 207/622 reads (33%) | catalogued as rs748910521; called by muse, mutect2, varscan2
- RNF123 | c.1227C>T p.I409= | Silent (SNP) | VAF 66/223 reads (30%) | catalogued as rs746190835, COSV59684321; called by muse, mutect2, varscan2
- SHANK3 | c.1740G>A p.R580= | Silent (SNP) | VAF 65/120 reads (54%) | called by muse, mutect2, varscan2
- TMCO4 | c.861C>T p.L287= | Silent (SNP) | VAF 72/208 reads (35%) | catalogued as rs1267063539, COSV53876909; called by muse, mutect2, varscan2
- VCP | c.1086C>G p.R362= | Silent (SNP) | VAF 138/373 reads (37%) | called by muse, mutect2, varscan2
- VSIG1 | c.1068G>A p.S356= | Silent (SNP) | VAF 98/133 reads (74%) | catalogued as rs745893510; called by muse, mutect2, varscan2
- ZNF304 | c.1686T>C p.S562= | Silent (SNP) | VAF 67/212 reads (32%) | catalogued as rs756225586; called by muse, mutect2, varscan2
- ADGRE4P | n.2232A>C | RNA (SNP) | VAF 45/161 reads (28%) | called by muse, mutect2, varscan2
- MORN1 | c.538-4639_538-4638del | Intron (DEL) | VAF 21/87 reads (24%) | called by mutect2, pindel, varscan2
- RNA5-8SP2 | chr16:34159728 C>T | 5'Flank (SNP) | VAF 82/217 reads (38%) | called by muse, mutect2, varscan2
